Somatic mutation profile of tumor specimen MP2PRT-PATSJE-TMP1-A (aliquot MP2PRT-PATSJE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATSJE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,152 days).
Specimen MP2PRT-PATSJE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3147d186-bd9e-4277-b41f-f1a45cc855d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATSJE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATSJE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b42132b8-c23a-40aa-b102-68d9c2353aef

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 2, 3'Flank 1, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 94/266 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEND1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 276/742 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs750922024, COSV57195136; called by muse, mutect2, varscan2
- KIF2B | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937705504, COSV52132788; called by muse, mutect2, varscan2
- MISP | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 222/614 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs372409482; called by muse, mutect2, varscan2
- PLAUR | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 151/362 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV55391507; called by muse, mutect2, varscan2
- SRCAP | c.4001delinsTGG p.P1334Lfs*10 | Frame Shift Ins (INS) | VAF 211/615 reads (34%) | catalogued as COSV52669324; called by mutect2*, pindel, varscan2*
- ANXA2R | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 50/449 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTTNBP2 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CYFIP2 | c.3140_3141insTCCTTCTTTTTTTGCT p.H1048Pfs*16 (on ENST00000616178 / NM_001291722.2; = p.H1023Pfs*16 on NM_014376.4) | Frame Shift Ins (INS) | VAF 43/172 reads (25%) | called by mutect2, pindel, varscan2
- DYTN | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- MROH9 | c.2008G>T p.G670C | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NUTM2B | c.1301C>A p.P434Q | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); called by muse, varscan2
- SORCS3 | c.2293C>T p.Q765* | Nonsense Mutation (SNP) | VAF 73/203 reads (36%) | called by muse, mutect2, varscan2
- FMNL2 | c.1788G>A p.P596= | Silent (SNP) | VAF 107/327 reads (33%) | catalogued as rs1187869405, COSV56489821; called by muse, mutect2, varscan2
- MISP | c.1104G>A p.E368= | Silent (SNP) | VAF 310/730 reads (42%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins CC | 3'Flank (INS) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- SMAD6 | c.*446G>A | 3'UTR (SNP) | VAF 24/59 reads (41%) | catalogued as rs191115503; called by muse, mutect2, varscan2
- SORBS2 | c.-197-6000G>A | Intron (SNP) | VAF 37/219 reads (17%) | catalogued as rs747780742, COSV52997485; called by muse, mutect2, varscan2
